Somatic mutation profile of tumor specimen MMRF_2116_1_BM_CD138pos (aliquot MMRF_2116_1_BM_CD138pos_T1_KHS5U_L08675) from MMRF case MMRF_2116, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 57.0 years (20,805 days).
Specimen MMRF_2116_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f0dfe92-7562-485f-b1c0-76c2829998d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2116_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2116_1_PB_Whole_C2_KHS5U_L08676; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7024a53e-debf-4754-81dd-d930a1d4c0b8

The open-access MAF lists 66 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, 3'UTR 19, Intron 9, 5'UTR 7, Silent 4, 5'Flank 3, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 24/77 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- AFAP1 | c.1223C>T p.T408M | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs774337434, COSV61797596; called by muse, mutect2, varscan2
- CACNA1I | c.1634C>T p.T545M | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs60975716, COSV104414641; called by muse, mutect2, varscan2
- COL22A1 | c.4466C>T p.P1489L | Missense Mutation (SNP) | VAF 52/131 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs757031031, COSV57329821, COSV57366824; called by muse, mutect2, varscan2
- FOXF2 | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.9); PolyPhen benign (0.005); catalogued as rs1289612903; called by muse, mutect2, varscan2
- IGLL5 | c.10A>C p.K4Q | Missense Mutation (SNP) | VAF 54/57 reads (95%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.019); catalogued as rs771808845; called by muse, mutect2, varscan2
- IGLL5 | c.107A>G p.H36R | Missense Mutation (SNP) | VAF 30/31 reads (97%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0.142); catalogued as rs544159503, COSV73251092; called by muse, mutect2, varscan2
- KIRREL1 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.188); catalogued as rs1050039797, COSV63285795; called by muse, mutect2
- RBM10 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61307803; called by muse, mutect2, varscan2
- AGBL2 | c.728G>A p.R243K | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.096); called by muse, mutect2
- CCDC168 | c.3459G>A p.M1153I | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- H2BC12 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- KIAA0319 | c.1656G>T p.Q552H | Missense Mutation (SNP) | VAF 59/131 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- LRFN2 | c.620A>T p.N207I | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC9 | c.1745C>T p.P582L | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- NEXMIF | c.1405T>G p.S469A | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- OVCH1 | c.2909T>C p.L970P | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PCDHGB4 | c.940T>C p.S314P | Missense Mutation (SNP) | VAF 43/260 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- STXBP1 | c.571T>G p.Y191D | Missense Mutation (SNP) | VAF 81/146 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TMF1 | c.2863G>A p.E955K | Missense Mutation (SNP) | VAF 36/57 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- TRBV4-2 | c.313T>C p.S105P | Missense Mutation (SNP) | VAF 120/287 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WDR47 | c.2345A>T p.D782V (on ENST00000369962 / NM_001142551.2; = p.D783V on NM_014969.5) | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAMSAP3 | c.1569C>A p.P523= | Silent (SNP) | VAF 481/915 reads (53%) | catalogued as COSV50336397; called by muse, mutect2, varscan2
- COL9A3 | c.555C>T p.P185= | Silent (SNP) | VAF 8/42 reads (19%) | called by mutect2, varscan2
- PCDHA5 | c.1860G>A p.P620= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as rs782817959; called by muse, mutect2, varscan2
- U2SURP | c.618C>G p.L206= | Silent (SNP) | VAF 58/106 reads (55%) | called by muse, mutect2, varscan2
- APPL1 | c.*1933T>C | 3'UTR (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- ATXN7 | c.500-12041G>A | Intron (SNP) | VAF 54/324 reads (17%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021361 G>C | 5'Flank (SNP) | VAF 58/139 reads (42%) | catalogued as COSV55849380; called by muse, mutect2, varscan2
- BIRC3 | c.-2251_-2248del | 5'UTR (DEL) | VAF 110/194 reads (57%) | called by pindel, varscan2
- CACNA1D | c.5040+185G>A | Intron (SNP) | VAF 20/29 reads (69%) | called by muse, mutect2, varscan2
- CPLX1 | c.*1432A>T | 3'UTR (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- DPP10 | c.*1408T>C | 3'UTR (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- EHF | c.*123G>T | 3'UTR (SNP) | VAF 34/261 reads (13%) | called by muse, mutect2, varscan2
- EIPR1 | c.259+19075G>A | Intron (SNP) | VAF 102/210 reads (49%) | catalogued as rs754415682; called by muse, mutect2, varscan2
- FAM71F1 | c.*54C>T | 3'UTR (SNP) | VAF 318/960 reads (33%) | called by muse, mutect2, varscan2
- GRIN3A | c.-409C>A | 5'UTR (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2, varscan2
- HMG20B | c.147+266G>T | Intron (SNP) | VAF 22/45 reads (49%) | catalogued as rs1424000658; called by muse, mutect2, varscan2
- IL17A | c.*53C>G | 3'UTR (SNP) | VAF 38/75 reads (51%) | called by muse, mutect2, varscan2
- KLHL1 | c.-149G>C | 5'UTR (SNP) | VAF 5/44 reads (11%) | catalogued as rs544464374; called by mutect2, varscan2
- KPNA4 | c.*3772A>G | 3'UTR (SNP) | VAF 23/128 reads (18%) | called by muse, mutect2, varscan2
- LTB | c.209-87C>T | Intron (SNP) | VAF 52/120 reads (43%) | called by muse, mutect2, varscan2
- MLLT6 | c.*3744C>G | 3'UTR (SNP) | VAF 42/152 reads (28%) | called by muse, mutect2, varscan2
- MON2 | c.-211C>G | 5'UTR (SNP) | VAF 85/179 reads (47%) | called by muse, mutect2, varscan2
- OGA | c.1984+644del | Intron (DEL) | VAF 4/28 reads (14%) | catalogued as rs202057076; called by pindel, varscan2
- PHOX2B | c.*489A>T | 3'UTR (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- PPARGC1A | c.*2789G>T | 3'UTR (SNP) | VAF 50/108 reads (46%) | called by muse, mutect2, varscan2
- PREB | c.-115G>T | 5'UTR (SNP) | VAF 115/189 reads (61%) | called by muse, mutect2, varscan2
- PRKAA2 | c.*3792A>T | 3'UTR (SNP) | VAF 24/76 reads (32%) | called by muse, mutect2, varscan2
- RAD17 | chr5:69370988 T>G | 5'Flank (SNP) | VAF 27/41 reads (66%) | called by muse, varscan2
- RHOU | c.*508A>G | 3'UTR (SNP) | VAF 34/150 reads (23%) | called by muse, mutect2
- RHPN2P1 | n.2212C>A | RNA (SNP) | VAF 96/907 reads (11%) | called by muse, mutect2, varscan2
- SETD3 | c.849+62A>G | Intron (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- SLC7A2 | c.*2631C>T | 3'UTR (SNP) | VAF 17/42 reads (40%) | called by muse, mutect2, varscan2
- SORD | c.*741C>T | 3'UTR (SNP) | VAF 164/585 reads (28%) | called by muse, mutect2, varscan2
- SSUH2 | c.-3-673C>A | Intron (SNP) | VAF 31/226 reads (14%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.*4911A>G | 3'UTR (SNP) | VAF 29/255 reads (11%) | called by muse, mutect2
- TFCP2L1 | c.*6616C>A | 3'UTR (SNP) | VAF 75/144 reads (52%) | called by muse, mutect2, varscan2
- THAP5 | c.-23T>G | 5'UTR (SNP) | VAF 21/105 reads (20%) | called by muse, mutect2, varscan2
- TLR9 | c.-536C>T | 5'UTR (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- TMEM70 | c.*490G>A | 3'UTR (SNP) | VAF 8/97 reads (8%) | called by muse, mutect2
- TRIM51 | c.412-69T>A | Intron (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- UAP1L1 | chr9:137086490 G>C | 3'Flank (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- WBP1L | c.*2440C>G | 3'UTR (SNP) | VAF 4/74 reads (5%) | called by muse, mutect2
- WDR91 | c.*426C>T | 3'UTR (SNP) | VAF 71/112 reads (63%) | catalogued as rs1337637643; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173865856 C>G | 5'Flank (SNP) | VAF 94/204 reads (46%) | called by muse, mutect2, varscan2
